TCGA case TCGA-3U-A98F — Mesothelioma (TCGA-MESO)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026), part of The Cancer Genome Atlas (TCGA). Disease type: Mesothelial Neoplasms; Primary site: Heart, mediastinum, and pleura; Tissue source site: University of Chicago. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/24ea3cd5-c2e6-44f7-9658-78af7befeef7

Demographics
Sex at birth: male; Race: white; Ethnicity: not hispanic or latino; Country of residence at enrollment: United States; Age at index: 73 years; Vital status: Dead; Days to death: 536 days (1.5 years).

Diagnoses (5)
1. Mesothelioma, biphasic, malignant (the primary disease): ICD-O-3 morphology code: 9053/3; ICD-10 code: C45.0; Tissue or organ of origin: Pleura, NOS; Site of resection or biopsy: Pleura, NOS; Laterality: Right; Classification of tumor: primary; Age at diagnosis: 73.7 years (26,926 days); Year of diagnosis: 2012; Method of diagnosis: Biopsy; AJCC staging edition: 7th; AJCC pathologic T: T3; AJCC pathologic N: N0; AJCC pathologic M: M0; AJCC pathologic stage: Stage III; Prior malignancy: no; Synchronous malignancy: No; Prior treatment: No; Days to last follow up: 536 days (1.5 years).
   Pathology details: Consistent pathology review: Yes.
   Treatment given: Treatment type: Radiation Therapy, NOS; Days to treatment start: 118 days; Days to treatment end: 120 days; Treatment dose: 21 Gy; Number of fractions: 3; Treatment anatomic sites: Regional Site.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Carboplatin + Pemetrexed; Days to treatment start: 162 days; Days to treatment end: 302 days; Treatment outcome: Stable Disease.
   Treatment given: Treatment type: Targeted Molecular Therapy; Therapeutic agents: Clinical Trial Agent; Days to treatment start: 379 days (1.0 years); Days to treatment end: 463 days (1.3 years); Treatment outcome: Progressive Disease; Clinical trial indicator: Yes.
   Recorded as not given: Pleurodesis, NOS, prior to procurement.
2. Recurrence of diagnosis 1 (Mesothelioma, biphasic, malignant), site: Thorax, NOS. Age at diagnosis: 74.7 years (27,291 days); Days to diagnosis: 365 days (1.0 years); Prior treatment: Yes.
   Recorded as not given: Surgery, NOS, for recurrent disease; Surgery, NOS, for progressive disease.
3. Metastasis of diagnosis 1 (Mesothelioma, biphasic, malignant), site: Vertebral column. Age at diagnosis: 74.9 years (27,366 days); Days to diagnosis: 440 days (1.2 years); Prior treatment: Yes.
4. Diagnosis record without a diagnosis name: Tumor of origin: diagnosis 1 of this record; Age at diagnosis: 75.0 years (27,389 days); Days to diagnosis: 463 days (1.3 years); Prior treatment: Yes.
   Recorded as not given: Surgery, NOS.
5. Progression of diagnosis 1 (Mesothelioma, biphasic, malignant). Age at diagnosis: 75.0 years (27,389 days); Days to diagnosis: 463 days (1.3 years); Prior treatment: Yes.
   Recorded as not given: Surgery, NOS, for progressive disease.

Follow-up (7 entries)
- Day 365 (post initial treatment): Progression or recurrence: Yes; Progression or recurrence type: Local; Days to progression: 365 days (1.0 years).
- Day 365 (post initial treatment): Progression or recurrence: Yes; Progression or recurrence type: Locoregional; Progression or recurrence anatomic site: Thorax, NOS; Days to recurrence: 365 days (1.0 years).
- Day 440 (post initial treatment): Progression or recurrence: Yes; Progression or recurrence type: Distant; Progression or recurrence anatomic site: Vertebral column; Days to progression: 440 days (1.2 years).
- Day 463 (post initial treatment): Disease response: With Tumor; Progression or recurrence: Yes; Progression or recurrence type: Local; Days to progression: 463 days (1.3 years).
- Days to follow up: 536 days (1.5 years); Disease response: With Tumor.
- ECOG performance status: 1; Timepoint: Preoperative.
- Imaging anatomic site: Pleura; Imaging suv max: 8.7; Timepoint: Prior to Treatment.

Molecular and laboratory tests
- Creatinine 0.7 mg/dL [Blood test normal range lower: 0.5; Blood test normal range upper: 1.4].

Exposures
- Exposure type: Asbestos; Exposure source: Occupational.
- Occupation type: Manufacturing Labourers.

Family history
- Relative with cancer history: yes; Relationship type: Sibling; Relationship primary diagnosis: Thyroid Cancer.
- Relative with cancer history: yes; Relationship type: Parent; Relationship primary diagnosis: Prostate Cancer.

Biospecimens (3 samples; slide percentages are pathologist estimates recorded by GDC per slide)
- Sample TCGA-3U-A98F-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT; Initial weight: 490 mg.
  Slide TCGA-3U-A98F-01A-01-TSA: Section location: Top; Percent tumor cells: 100; Percent tumor nuclei: 80; Percent normal cells: 0; Percent necrosis: 0; Percent stromal cells: 0; Percent lymphocyte infiltration: 2; Percent monocyte infiltration: 0; Percent neutrophil infiltration: 0.
- Sample TCGA-3U-A98F-01Z: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE; Days to sample procurement: 0 days.
- Sample TCGA-3U-A98F-10A: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS.

Additional fields from the legacy TCGA clinical forms (Biospecimen Core Resource XML)
- Enrollment form: Prospective collection: No; Retrospective collection: Yes; History neoadjuvant treatment: No; Pleurodesis performed prior: No; Tumor status: With tumor; History asbestos exposure: Yes; Primary occupation: Other, please specify; Occupation primary: Helped build recreational vehicles (manufacturing). Worked at industrial plant, steam operated  with asbestos insulated pipes.
- Primary pathology: Submitted tumor site: Pleura; Histologic diagnosis: Biphasic mesothelioma.
- Follow-up form: Lost to follow-up: No; Tumor status: With tumor; Performance status timing: Post-Adjuvant Therapy.
- Drug treatment 1: Clinical trial drug classification: anti-CTLA4 monoclonal antibody; Treatment best response: Clinical Progressive Disease.
- Drug treatment 3: Pharmaceutical therapy drug name: Pemetrexed (Alimta).

Curated follow-up endpoints (TCGA Pan-Cancer Clinical Data Resource, Liu et al., Cell 2018; times are days from initial pathologic diagnosis to the event or to last contact): overall survival: event (deceased), 536 days; disease-specific survival: event (death attributed to the disease, the Clinical Data Resource's approximation), 536 days; progression-free interval: event (progression, recurrence, new primary tumor or death with tumor), 365 days.

Tumor purity and ploidy (ABSOLUTE, TCGA Pan-Cancer Atlas; aliquot TCGA-3U-A98F-01A-11D-A39Q-01): tumor purity 0.94, ploidy 3.41, whole-genome doublings 1.
